Somatic mutation profile of tumor specimen TCGA-17-Z036-01A (aliquot TCGA-17-Z036-01A-01W-0746-08) from TCGA case TCGA-17-Z036, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z036-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c7140ef-b956-443a-bc92-ced7dadd9a9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z036-11A (Solid Tissue Normal), aliquot TCGA-17-Z036-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1aac5e55-a31c-4088-950f-9a5ef25c2ad8

The open-access MAF lists 80 somatic variants for this specimen: 63 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 14, Nonsense Mutation 3, Intron 3, Frame Shift Del 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCF3 | c.1565G>A p.C522Y | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs758584828; called by muse, mutect2, varscan2
- AKR1D1 | c.284C>A p.P95Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs756506371; called by muse, mutect2, varscan2
- ALK | c.1625C>G p.P542R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66571802, COSV66588105; called by muse, mutect2, varscan2
- APC | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as CM014883, COSV57350136, COSV57362856; called by muse, mutect2, varscan2
- APC | c.4462_4480del p.L1488Kfs*13 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as COSV57350148; called by pindel, varscan2
- ASXL3 | c.5386G>A p.V1796I | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs755015351, COSV52456992; called by muse, mutect2, varscan2
- ATP10A | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs777246990; called by muse, mutect2, varscan2
- BBS9 | c.2273C>T p.P758L (on ENST00000242067 / NM_001348036.1; = p.P718L on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757754301, COSV54165316, COSV54173388; called by muse, mutect2, varscan2
- BPGM | c.538G>T p.G180C | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61326337; called by muse, mutect2, varscan2
- CACNA1C | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs377737331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPB1 | c.1172A>T p.E391V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759354703; called by muse, mutect2, varscan2
- DZIP1L | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs138745459; called by muse, mutect2, varscan2
- GIP | c.355C>G p.P119A | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781678802, COSV62467125; called by muse, mutect2
- GJA8 | c.276C>G p.Y92* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV53790852, COSV99569566; called by muse, mutect2, varscan2
- GMPPA | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309109561; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.502); catalogued as rs1418373541; called by muse, mutect2
- LATS2 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs113238499, COSV66873645, COSV66876566; called by muse, mutect2, varscan2
- NAV3 | c.5915C>T p.T1972I (on ENST00000397909 / NM_001024383.2; = p.T1950I on NM_014903.6) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV99890067; called by muse, mutect2, varscan2
- OR4N2 | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773189757, COSV60051720; called by muse, mutect2
- PAPOLA | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs753661400; called by muse, mutect2, varscan2
- PENK | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs556758464; called by muse, mutect2, varscan2
- PLCL1 | c.3019C>T p.H1007Y | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs1476880652; called by muse, mutect2, varscan2
- RALGAPA2 | c.2407G>C p.G803R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.249); catalogued as rs1169642026; called by muse, mutect2, varscan2
- RPTOR | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100157465, COSV60810057; called by muse, mutect2, varscan2
- STIM2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748529061; called by muse, mutect2, varscan2
- TRIM45 | c.1679C>A p.S560Y | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56712783; called by muse, mutect2, varscan2
- ZNF536 | c.-2G>T | Splice Region (SNP) | VAF 27/80 reads (34%) | catalogued as COSV62827772; called by muse, mutect2, varscan2
- ZNF567 | c.263A>G p.K88R (on ENST00000536254 / NM_001322913.1; = p.K57R on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs770170016; called by muse, mutect2, varscan2
- A2M | c.2270C>T p.T757I | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ABCC5 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.11081A>C p.K3694T | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ARHGAP27 | c.1869C>G p.S623R (on ENST00000428638 / NM_001282290.1; = p.S282R on NM_199282.3) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL17A1 | c.2252A>T p.Q751L | Missense Mutation (SNP) | VAF 106/349 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DMAP1 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DOCK2 | c.4467G>T p.Q1489H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- HDAC1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- KEAP1 | c.1499del p.I500Tfs*4 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- KRBA2 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LMBRD2 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | called by muse, varscan2
- LPGAT1 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- MBD6 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.365); called by muse, mutect2
- MMP1 | c.1277T>A p.V426D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOT | c.612C>G p.D204E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- N4BP1 | c.2677A>G p.M893V | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NALCN | c.847G>T p.V283L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NSD3 | c.3891A>C p.E1297D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10A6 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2A5 | c.578G>C p.W193S | Missense Mutation (SNP) | VAF 100/387 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR2M3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR8D4 | c.555T>G p.I185M | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PLEKHA7 | c.1556C>A p.T519N | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAB17 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RHO | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDS | c.758C>A p.A253D | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC12A5 | c.1430G>A p.G477E (on ENST00000454036 / NM_001134771.2; = p.G454E on NM_020708.5) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC12A8 | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- SLITRK2 | c.1205A>T p.D402V | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SMARCAL1 | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31E1 | c.4090_4095del p.C1364_H1365del | In Frame Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel
- TAOK1 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TMC3 | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- C4orf50 | c.813G>C p.P271= (on ENST00000324058; = p.P1503= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs368880548; called by muse, mutect2, varscan2
- DCAF6 | c.1095A>T p.G365= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- IRF9 | c.306C>T p.R102= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs776471639; called by muse, mutect2, varscan2
- KANK4 | c.1269G>A p.L423= | Silent (SNP) | VAF 56/152 reads (37%) | called by muse, mutect2, varscan2
- KCNA6 | c.1563A>T p.A521= | Silent (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1500C>A p.A500= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV54440338; called by muse, mutect2, varscan2
- MMP1 | c.1278T>A p.V426= | Silent (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.3864G>A p.V1288= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1276481237; called by muse, mutect2, varscan2
- POLG2 | c.66G>A p.G22= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- RTP1 | c.696A>T p.S232= | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as rs750105125; called by muse, mutect2, varscan2
- SCPEP1 | c.207C>A p.P69= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- SLC15A4 | c.810C>T p.S270= | Silent (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- SOS1 | c.3417T>C p.S1139= | Silent (SNP) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- UGT2A2 | c.240T>C p.F80= | Silent (SNP) | VAF 64/177 reads (36%) | catalogued as rs748886353; called by muse, mutect2, varscan2
- FBXL7 | c.740-1230A>T | Intron (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- NDUFA5 | c.66+454T>C | Intron (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2
- SLC7A2 | c.1195+377A>G | Intron (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
